Somatic mutation profile of tumor specimen 0DQQBR from CCDI case PBCEWY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 20.6 years (7,506 days).
Specimen 0DQQBR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f3e8fb9-ae84-44fa-adb0-d9a5b1ba10ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQQCL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fecf9c9-788b-4e32-88d7-51ee22b16ccf

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MBOAT7 | c.758_778del p.E253_A259del | In Frame Del (DEL) | VAF 86/716 reads (12%) | catalogued as rs750035706; ClinVar: pathogenic; called by mutect2, varscan2
- FRAS1 | c.4631C>T p.P1544L | Missense Mutation (SNP) | VAF 47/766 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53612229; called by muse, mutect2
- KCNQ3 | c.1216G>A p.V406I | Missense Mutation (SNP) | VAF 85/701 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs144474368; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SLIT1 | c.3628G>A p.D1210N | Missense Mutation (SNP) | VAF 79/753 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs748040766, COSV56582312; called by muse, mutect2, varscan2
- TRPM3 | c.2158G>A p.E720K (on ENST00000357533 / NM_001366142.2; = p.E563K on NM_020952.6) | Missense Mutation (SNP) | VAF 83/587 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs752221707, COSV62587641; called by muse, mutect2, varscan2
- CCDC43 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 81/683 reads (12%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SUPT6H | c.4843C>T p.P1615S | Missense Mutation (SNP) | VAF 21/856 reads (2%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2
- TOP2B | c.1870G>C p.E624Q (on ENST00000264331 / NM_001330700.2; = p.E619Q on NM_001068.3) | Missense Mutation (SNP) | VAF 55/421 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TTC7A | c.430T>C p.Y144H | Missense Mutation (SNP) | VAF 26/828 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2
- GABRA4 | c.798G>A p.P266= | Silent (SNP) | VAF 88/622 reads (14%) | catalogued as rs541280213, COSV51925155; called by muse, mutect2, varscan2
- LONRF3 | c.381C>T p.D127= | Silent (SNP) | VAF 108/730 reads (15%) | called by muse, mutect2, varscan2
- NOS2 | c.171G>A p.P57= | Silent (SNP) | VAF 27/565 reads (5%) | catalogued as rs773527134, COSV100569762, COSV58223187; called by muse, mutect2
